Somatic mutation profile of tumor specimen MMRF_1408_1_BM_CD138pos (aliquot MMRF_1408_1_BM_CD138pos_T1_KAS5U_L00645) from MMRF case MMRF_1408, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.8 years (22,934 days).
Specimen MMRF_1408_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abf4bf2c-7e54-40f3-a4be-14961f065b5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1408_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1408_1_PB_Whole_C2_KAS5U_L00653; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fedd6135-84ca-4370-bada-256c5bb6442f

The open-access MAF lists 97 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 24, Intron 14, Silent 13, Frame Shift Del 4, 5'UTR 3, RNA 2, 5'Flank 2, 3'Flank 1, Frame Shift Ins 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL3 | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs751167134, COSV54439652; called by muse, mutect2, varscan2
- AMHR2 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs371318635; called by muse, varscan2
- CACNA2D4 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373696894; called by muse, mutect2, varscan2
- CCDC28A | c.80dup p.N27Kfs*7 | Frame Shift Ins (INS) | VAF 67/106 reads (63%) | catalogued as rs756347761; called by mutect2, varscan2
- FAT1 | c.2305A>G p.M769V | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as rs778456772; called by muse, mutect2, varscan2
- IGHV1-69 | c.162C>G p.S54R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs782296104; called by muse, varscan2
- IGLV1-44 | c.133A>G p.S45G | Missense Mutation (SNP) | VAF 62/69 reads (90%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.026); catalogued as rs532669068; called by muse, varscan2
- IGLV1-44 | c.134G>A p.S45N | Missense Mutation (SNP) | VAF 64/69 reads (93%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.038); catalogued as rs772458317; called by muse, varscan2
- IGLV4-60 | c.334T>C p.Y112H | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.324); catalogued as rs768098610; called by muse, varscan2
- IGLV5-45 | c.167G>A p.W56* | Nonsense Mutation (SNP) | VAF 36/36 reads (100%) | catalogued as rs780108716; called by muse, varscan2
- KIAA1522 | c.469C>T p.R157W (on ENST00000373480 / NM_001198972.2; = p.R216W on NM_020888.3) | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760262368, COSV53868034; called by muse, mutect2, varscan2
- MST1 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs1224553793, COSV56534007; called by muse, mutect2, varscan2
- PBRM1 | c.2506C>T p.R836W | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438592568, COSV56266126; called by muse, mutect2, varscan2
- PCDHGA6 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.281); catalogued as COSV53910894; called by muse, mutect2, varscan2
- ZMYND11 | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV59077320; called by muse, mutect2, varscan2
- C16orf70 | c.798G>A p.M266I | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTCF | c.249_251dup p.P84dup | In Frame Ins (INS) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- FEM1C | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FIGNL1 | c.851A>G p.N284S | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV1-69D | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- IGHV1-69D | c.162C>G p.S54R | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by mutect2, varscan2
- IGLV1-44 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 26/26 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- IGLV5-45 | c.159G>T p.R53S | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT tolerated (0.64); PolyPhen benign (0.005); called by muse, varscan2
- KLB | c.1324C>G p.Q442E | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KMT2A | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LHX2 | c.1181_1183delinsT p.P394Lfs*32 | Frame Shift Del (DEL) | VAF 75/258 reads (29%) | called by pindel, varscan2*
- LIMCH1 | c.2930G>A p.R977K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- MAGEC1 | c.1881C>G p.S627R | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- MIS18BP1 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MRC1 | c.3971A>G p.D1324G | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- PACSIN2 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- PIEZO2 | c.7802C>G p.P2601R | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SLC8B1 | c.1403G>A p.S468N | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- SPATA31D1 | c.908C>A p.A303D | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- TENT5C | c.573_577del p.L191Ffs*4 | Frame Shift Del (DEL) | VAF 5/75 reads (7%) | called by mutect2, pindel
- TENT5C | c.693del p.I231Mfs*36 | Frame Shift Del (DEL) | VAF 17/110 reads (15%) | called by mutect2, pindel, varscan2
- TENT5C | c.888del p.F296Lfs*13 | Frame Shift Del (DEL) | VAF 45/104 reads (43%) | called by mutect2, pindel, varscan2
- UNC93B1 | c.949A>T p.I317F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CAPN8 | c.279G>A p.T93= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs529585726; called by muse, mutect2, varscan2
- FBLN2 | c.240C>T p.R80= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs756357369, COSV99851278; called by muse, mutect2, varscan2
- GPR6 | c.534G>T p.S178= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV51573910; called by muse, mutect2, varscan2
- GREB1 | c.5754C>T p.L1918= | Silent (SNP) | VAF 55/163 reads (34%) | catalogued as rs369967332, COSV99303522; called by muse, mutect2, varscan2
- HS3ST3B1 | c.726G>A p.L242= | Silent (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- IGHV1-3 | c.162T>C p.H54= | Silent (SNP) | VAF 60/68 reads (88%) | catalogued as rs782462535; called by muse, mutect2, varscan2
- IGHV2-70D | c.261G>A p.R87= | Silent (SNP) | VAF 22/26 reads (85%) | called by muse, varscan2
- NRXN3 | c.654G>A p.K218= (on ENST00000557594 / NM_001272020.2; = p.K850= on NM_004796.6) | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV55355387; called by muse, varscan2
- OR56A5 | c.214C>T p.L72= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV60827316; called by muse, mutect2
- PCDHA13 | c.1527G>A p.S509= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV56474956, COSV56560246; called by muse, mutect2
- RYR2 | c.8244A>T p.S2748= | Silent (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- TMPRSS7 | c.111G>A p.P37= | Silent (SNP) | VAF 65/167 reads (39%) | catalogued as rs540320405, COSV69981987; called by muse, mutect2, varscan2
- ZBTB16 | c.1509C>T p.S503= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs752951049, COSV100251141, COSV100251438; called by muse, mutect2, varscan2
- ABR | c.*16C>T | 3'UTR (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- AC116366.2 | c.-638+119T>A | Intron (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2
- ANKRD42 | c.*202G>C | 3'UTR (SNP) | VAF 65/205 reads (32%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021602 G>A | 5'Flank (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- DHRS2 | c.421-1459C>T | Intron (SNP) | VAF 28/49 reads (57%) | called by muse, mutect2, varscan2
- DIS3 | chr13:72781942 A>G | 5'Flank (SNP) | VAF 43/76 reads (57%) | called by muse, mutect2, varscan2
- DSEL | c.*2938G>C | 3'UTR (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- FABP12 | c.*44A>G | 3'UTR (SNP) | VAF 56/127 reads (44%) | called by muse, mutect2, varscan2
- FLJ40288 | n.1903G>C | RNA (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- IGLV1-44 | c.-34G>C | 5'UTR (SNP) | VAF 19/20 reads (95%) | called by muse, mutect2, varscan2
- IGLV1-44 | c.-33G>A | 5'UTR (SNP) | VAF 20/21 reads (95%) | called by muse, mutect2, varscan2
- KCNU1 | c.2737-1998G>T | Intron (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- KIF19 | c.*356dup | 3'UTR (INS) | VAF 23/102 reads (23%) | called by mutect2, pindel, varscan2
- KRTAP24-1 | c.*270A>G | 3'UTR (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- LINC01561 | n.1779G>A | RNA (SNP) | VAF 3/46 reads (7%) | catalogued as rs1047652382; called by muse, mutect2
- LTB | c.208+53C>G | Intron (SNP) | VAF 31/106 reads (29%) | called by muse, mutect2, varscan2
- MAP3K9 | c.*1241C>G | 3'UTR (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- MCF2L | c.459+1485G>A | Intron (SNP) | VAF 32/78 reads (41%) | catalogued as rs1328242663; called by muse, mutect2, varscan2
- MFAP3L | c.*3467C>A | 3'UTR (SNP) | VAF 53/81 reads (65%) | called by muse, mutect2, varscan2
- MKI67 | c.*785T>C | 3'UTR (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- MPP6 | c.*1909A>G | 3'UTR (SNP) | VAF 16/40 reads (40%) | called by muse, varscan2
- NAALADL2 | c.*274A>T | 3'UTR (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2
- NUP160 | c.1102-4950G>A | Intron (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- OSR1 | chr2:19348436 C>A | 3'Flank (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- PCNX2 | c.4136-11T>C | Intron (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- PIK3CD | c.1471-66G>A | Intron (SNP) | VAF 3/28 reads (11%) | catalogued as rs940524812; called by muse, mutect2
- PITX2 | c.*3C>T | 3'UTR (SNP) | VAF 15/40 reads (38%) | catalogued as rs780613951; called by muse, mutect2, varscan2
- PLPPR1 | c.*1030G>T | 3'UTR (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- PRR12 | c.51+333C>T | Intron (SNP) | VAF 26/100 reads (26%) | called by muse, mutect2, varscan2
- PUM2 | c.*1559C>T | 3'UTR (SNP) | VAF 30/100 reads (30%) | called by muse, mutect2, varscan2
- RABL6 | c.705+159C>G | Intron (SNP) | VAF 20/88 reads (23%) | called by muse, mutect2
- RAP2A | c.*299C>T | 3'UTR (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- RBM4 | c.412+451T>G | Intron (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- REG3G | c.*24_*28del | 3'UTR (DEL) | VAF 22/78 reads (28%) | called by mutect2, pindel, varscan2
- ROPN1 | c.116+958T>G | Intron (SNP) | VAF 32/87 reads (37%) | called by mutect2, varscan2
- RPS6KA5 | c.*791G>A | 3'UTR (SNP) | VAF 22/39 reads (56%) | catalogued as rs1182272906; called by muse, mutect2, varscan2
- SERPINA10 | c.-6G>A | 5'UTR (SNP) | VAF 26/56 reads (46%) | catalogued as rs757642665; called by muse, mutect2, varscan2
- SLC7A9 | c.749+102C>A | Intron (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2, varscan2
- SSBP2 | c.*7206G>A | 3'UTR (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- STON1 | c.*2038C>T | 3'UTR (SNP) | VAF 6/42 reads (14%) | catalogued as rs1014443154; called by muse, mutect2, varscan2
- STON1 | c.*3123T>C | 3'UTR (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- TAF2 | c.*1101_*1137del | 3'UTR (DEL) | VAF 26/73 reads (36%) | called by mutect2, pindel
- TCP10L3 | n.2619-704A>G | Intron (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- THBS1 | c.*133G>T | 3'UTR (SNP) | VAF 22/416 reads (5%) | called by muse, mutect2
- TRIB3 | c.*827A>T | 3'UTR (SNP) | VAF 8/40 reads (20%) | catalogued as rs766523952; called by muse, mutect2, varscan2
- UQCC2 | c.*26C>T | 3'UTR (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
